Somatic mutation profile of tumor specimen MMRF_1403_1_BM_CD138pos (aliquot MMRF_1403_1_BM_CD138pos_T1_KAS5U_L00643) from MMRF case MMRF_1403, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.7 years (22,895 days).
Specimen MMRF_1403_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0307a9fa-9cae-46e0-a24b-40aa1bda5c8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1403_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1403_1_PB_CD3pos_C2_KAS5U_L00651; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0ecba27-cb2c-423a-be4c-85ddb49f2775

The open-access MAF lists 341 somatic variants for this specimen: 108 protein-altering or splice-affecting, 51 silent, 182 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 95, Missense Mutation 88, Silent 51, Intron 50, 5'UTR 16, Nonsense Mutation 11, 5'Flank 9, RNA 8, 3'Flank 4, Splice Region 3, Frame Shift Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC131160.1 | c.24G>C p.Q8H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as rs1250304121; called by muse, mutect2, varscan2
- ADAMTS9 | c.5183G>A p.R1728H | Missense Mutation (SNP) | VAF 54/97 reads (56%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs202044216, COSV55782203; called by muse, varscan2
- AP3B1 | c.1910C>G p.S637C | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV54876724; called by muse, mutect2, varscan2
- ARHGAP17 | c.2590G>A p.V864M (on ENST00000289968 / NM_001006634.3; = p.V786M on NM_018054.6) | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); catalogued as rs368716312; called by muse, mutect2, varscan2
- ATM | c.3285-1G>C p.X1095_splice | Splice Site (SNP) | VAF 17/27 reads (63%) | catalogued as COSV99587196; called by muse, mutect2, varscan2
- BRINP2 | c.2177G>A p.R726Q | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs780937563, COSV100838220; called by muse, mutect2, varscan2
- CELSR2 | c.8227G>A p.E2743K | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.968); catalogued as COSV54778352; called by muse, mutect2, varscan2
- CEP295 | c.1417G>A p.G473R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs540888367; called by muse, varscan2
- COL6A6 | c.1715T>A p.I572N | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV62026616; called by muse, mutect2, varscan2
- COX15 | c.36G>C p.L12F | Missense Mutation (SNP) | VAF 79/153 reads (52%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs750087100; called by muse, mutect2, varscan2
- CPA1 | c.845C>G p.S282C | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50571860; called by muse, mutect2, varscan2
- DIPK1C | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs944321376, COSV59724096; called by muse, mutect2, varscan2
- DNAH8 | c.5636G>A p.R1879K | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV59429257; called by muse, mutect2, varscan2
- DSG3 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99934706; called by muse, mutect2, varscan2
- DYNC1H1 | c.10267G>A p.A3423T | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs762851661, COSV100795731; called by muse, mutect2, varscan2
- EDIL3 | c.908G>C p.R303T | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT deleterious (0.05); PolyPhen benign (0.196); catalogued as COSV56879415; called by muse, mutect2, varscan2
- FUCA2 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs773098292; called by muse, mutect2, varscan2
- GINS1 | c.76-4C>G | Splice Region (SNP) | VAF 48/151 reads (32%) | catalogued as COSV52465830; called by muse, mutect2, varscan2
- GON4L | c.6625G>A p.E2209K | Missense Mutation (SNP) | VAF 63/279 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV55187518; called by muse, mutect2, varscan2
- IGHV3-33 | c.228T>A p.N76K | Missense Mutation (SNP) | VAF 61/81 reads (75%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs372933523; called by muse, varscan2
- IGLL5 | c.325G>A p.G109S | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.119); catalogued as rs201857114, COSV66537362; called by muse, mutect2, varscan2
- IGLV2-8 | c.326G>A p.C109Y | Missense Mutation (SNP) | VAF 44/44 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as rs546127789; called by muse, mutect2, varscan2
- KIF1B | c.2602G>A p.D868N (on ENST00000377086 / NM_001365952.1; = p.D822N on NM_015074.3) | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV55805152; called by muse, mutect2, varscan2
- KPTN | c.994G>A p.G332R | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1310970053, COSV52637876; called by muse, mutect2, varscan2
- LNPK | c.909C>A p.F303L | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV55826637; called by muse, mutect2, varscan2
- LRWD1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs1261716822; called by muse, mutect2
- MICALL1 | c.1364C>A p.S455Y | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs946654700; called by muse, mutect2, varscan2
- MYC | c.437C>T p.S146L (on ENST00000377970; = p.S161L on NM_002467.6) | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV52367052; called by muse, mutect2, varscan2
- MYC | c.524G>A p.S175N (on ENST00000377970; = p.S190N on NM_002467.6) | Missense Mutation (SNP) | VAF 104/193 reads (54%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.903); catalogued as COSV52367488, COSV99419768; called by muse, mutect2, varscan2
- MYH3 | c.2959G>C p.D987H | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs1472919523; called by muse, mutect2, varscan2
- NAV1 | c.4375G>A p.D1459N | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772044973; called by muse, mutect2, varscan2
- NFRKB | c.650C>G p.S217* (on ENST00000446488 / NM_001143835.2; = p.S242* on NM_006165.3) | Nonsense Mutation (SNP) | VAF 24/51 reads (47%) | catalogued as COSV58757068; called by muse, mutect2, varscan2
- PAQR5 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 116/252 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.305); catalogued as COSV61818035; called by muse, mutect2, varscan2
- PIWIL1 | c.2146G>A p.E716K | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55346093; called by muse, mutect2, varscan2
- PTPRD | c.4961C>G p.S1654* | Nonsense Mutation (SNP) | VAF 49/129 reads (38%) | catalogued as COSV61930790; called by muse, mutect2, varscan2
- PTTG1IP | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100445901, COSV99044078; called by muse, mutect2, varscan2
- REM2 | c.1003C>T p.H335Y | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV57465737; called by muse, mutect2, varscan2
- SHROOM2 | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 50/52 reads (96%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.471); catalogued as rs370184337, COSV101098715; called by muse, mutect2, varscan2
- SYNE1 | c.18859G>A p.E6287K (on ENST00000367255 / NM_182961.4; = p.E6216K on NM_033071.3) | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as rs760324185, COSV55141335; called by muse, mutect2, varscan2
- TANC2 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.087); catalogued as rs778411760; called by muse, mutect2, varscan2
- TNFRSF12A | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.35); catalogued as rs752145330; called by muse, varscan2
- UNC13C | c.4885G>A p.E1629K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs200137468, COSV52872827; called by muse, mutect2, varscan2
- ZFP30 | c.1453C>T p.Q485* | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as COSV63623231; called by muse, mutect2, varscan2
- ZNF28 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 62/214 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as COSV100354496, COSV60422486; called by muse, mutect2, varscan2
- ZNF280B | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 71/73 reads (97%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs1045095792, COSV99081439; called by muse, mutect2, varscan2
- ABCA12 | c.1040C>T p.S347F (on ENST00000272895 / NM_173076.3; = p.S29F on NM_015657.3) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- ABI3BP | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANK3 | c.3366C>G p.I1122M (on ENST00000280772 / NM_001320874.2; = p.I256M on NM_001149.3) | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ATP13A1 | c.2245G>C p.D749H | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BEND3 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- C2orf42 | c.729G>C p.Q243H | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- C5orf47 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- CENPF | c.49C>G p.L17V | Missense Mutation (SNP) | VAF 80/160 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CEP128 | c.2623C>T p.Q875* | Nonsense Mutation (SNP) | VAF 15/24 reads (63%) | called by muse, mutect2, varscan2
- COL3A1 | c.3349G>A p.A1117T | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CTBP1 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- CTNNA2 | c.2026C>A p.P676T | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CYP4A22 | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- DAAM1 | c.2533G>A p.D845N | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DBT | c.209C>G p.S70* | Nonsense Mutation (SNP) | VAF 12/12 reads (100%) | called by muse, mutect2, varscan2
- DCTPP1 | c.150C>A p.F50L | Missense Mutation (SNP) | VAF 62/128 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); called by muse, varscan2
- DDX11 | c.1948+3G>A | Splice Region (SNP) | VAF 9/88 reads (10%) | called by mutect2, varscan2
- DNAJC7 | c.554G>A p.C185Y | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- DOCK4 | c.4021G>A p.D1341N | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- DRC1 | c.1218del p.E407Rfs*6 | Frame Shift Del (DEL) | VAF 9/50 reads (18%) | called by mutect2, pindel, varscan2
- FMNL3 | c.2353G>C p.V785L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FOXF2 | c.1217G>A p.R406K | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- GABBR1 | c.2173C>G p.L725V | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GREB1L | c.2263G>C p.E755Q | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- HFM1 | c.4294G>C p.D1432H | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- HSPA8 | c.518_520del p.I173del | In Frame Del (DEL) | VAF 18/44 reads (41%) | called by pindel, varscan2
- IRF1 | c.114G>T p.W38C | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ITGB5 | c.2272C>T p.Q758* | Nonsense Mutation (SNP) | VAF 38/81 reads (47%) | called by muse, mutect2, varscan2
- KDM5A | c.1702C>G p.R568G | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- KMT2D | c.5426A>G p.D1809G | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- LRP2 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.075); called by mutect2, varscan2
- MAN1B1 | c.1252C>T p.Q418* | Nonsense Mutation (SNP) | VAF 34/110 reads (31%) | called by muse, varscan2
- MCL1 | c.94G>A p.G32R | Missense Mutation (SNP) | VAF 38/542 reads (7%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2
- MEF2D | c.1480C>A p.L494M | Missense Mutation (SNP) | VAF 48/315 reads (15%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- MIA3 | c.4912G>A p.E1638K | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- MKI67 | c.5488G>C p.E1830Q | Missense Mutation (SNP) | VAF 55/68 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRS2 | c.405G>C p.M135I | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NACC2 | c.1055C>G p.S352C | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ODF3 | c.585C>A p.F195L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- OFD1 | c.2314C>A p.L772I | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT tolerated (0.27); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- PEX16 | c.694+5C>T | Splice Region (SNP) | VAF 29/134 reads (22%) | called by muse, mutect2, varscan2
- PPP6C | c.510C>G p.I170M | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- PTCH1 | c.1617_1624del p.C540Afs*84 | Frame Shift Del (DEL) | VAF 16/85 reads (19%) | called by mutect2, pindel, varscan2
- RMDN3 | c.706G>T p.E236* | Nonsense Mutation (SNP) | VAF 43/91 reads (47%) | called by muse, mutect2, varscan2
- RNF17 | c.3859T>C p.F1287L | Missense Mutation (SNP) | VAF 53/56 reads (95%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- RPGRIP1 | c.3071T>G p.L1024R | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- RTN4R | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 17/35 reads (49%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- SALL1 | c.1418G>T p.G473V | Missense Mutation (SNP) | VAF 33/33 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEMA3E | c.1906G>T p.D636Y | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SKOR2 | c.2875G>C p.E959Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- SPACA9 | c.394_395insCGGT p.N132Tfs*38 (on ENST00000356311 / NM_001316897.2; = p.N132Tfs*80 on NM_018956.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 58/196 reads (30%) | called by pindel, varscan2
- SPAG9 | c.1570G>T p.E524* (on ENST00000262013 / NM_001130528.3; = p.E510* on NM_003971.6) | Nonsense Mutation (SNP) | VAF 26/111 reads (23%) | called by muse, mutect2, varscan2
- SUDS3 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TCP11L2 | c.395T>A p.L132Q | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TET2 | c.3482G>C p.R1161T | Missense Mutation (SNP) | VAF 48/240 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM200A | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- TTC21B | c.2605C>G p.Q869E | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- TUT7 | c.3577C>T p.Q1193* | Nonsense Mutation (SNP) | VAF 15/117 reads (13%) | called by muse, mutect2, varscan2
- UBTD1 | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- UGP2 | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 30/121 reads (25%) | called by muse, mutect2, varscan2
- WBP4 | c.453G>C p.E151D | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- XK | c.585G>C p.K195N | Missense Mutation (SNP) | VAF 30/32 reads (94%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZNF415 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 65/142 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- AFM | c.1065T>A p.T355= | Silent (SNP) | VAF 30/58 reads (52%) | called by muse, mutect2
- ALOX5AP | c.111G>A p.Q37= | Silent (SNP) | VAF 49/53 reads (92%) | called by muse, mutect2, varscan2
- AMZ1 | c.936C>T p.I312= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs576714230, COSV100406645; called by muse, varscan2
- AP2A1 | c.192C>T p.F64= | Silent (SNP) | VAF 70/160 reads (44%) | called by muse, varscan2
- ARHGAP17 | c.303G>A p.E101= | Silent (SNP) | VAF 39/81 reads (48%) | catalogued as COSV51506284, COSV99253764; called by muse, mutect2, varscan2
- ART1 | c.48C>A p.L16= | Silent (SNP) | VAF 32/98 reads (33%) | called by muse, mutect2, varscan2
- ASB4 | c.735C>G p.V245= | Silent (SNP) | VAF 47/102 reads (46%) | called by muse, mutect2, varscan2
- ASB7 | c.120G>A p.P40= | Silent (SNP) | VAF 56/108 reads (52%) | catalogued as rs143205334; called by muse, mutect2, varscan2
- ATG2B | c.2481C>T p.F827= | Silent (SNP) | VAF 40/80 reads (50%) | called by muse, mutect2, varscan2
- BEX4 | c.132G>A p.Q44= | Silent (SNP) | VAF 29/55 reads (53%) | called by muse, mutect2, varscan2
- BORA | c.663T>C p.H221= (on ENST00000613797; = p.H146= on NM_024808.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/30 reads (100%) | called by muse, mutect2, varscan2
- CCT6B | c.9G>A p.A3= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV58490142; called by muse, mutect2
- CLCN6 | c.1614C>T p.I538= | Silent (SNP) | VAF 32/66 reads (48%) | called by muse, mutect2, varscan2
- DDX58 | c.369C>T p.I123= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV101152351, COSV65882978; called by muse, mutect2
- DHODH | c.495G>A p.Q165= | Silent (SNP) | VAF 19/38 reads (50%) | called by muse, mutect2, varscan2
- E2F3 | c.585C>T p.S195= | Silent (SNP) | VAF 37/76 reads (49%) | called by muse, mutect2, varscan2
- ELFN1 | c.153C>T p.Y51= | Silent (SNP) | VAF 69/162 reads (43%) | catalogued as rs148419230; called by muse, mutect2, varscan2
- EPOR | c.810G>A p.A270= | Silent (SNP) | VAF 40/89 reads (45%) | catalogued as rs1397127705; called by muse, mutect2, varscan2
- FAHD2A | c.858C>T p.F286= | Silent (SNP) | VAF 44/102 reads (43%) | called by muse, mutect2, varscan2
- FBXO27 | c.78G>C p.L26= | Silent (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- FOXE1 | c.315C>T p.L105= | Silent (SNP) | VAF 58/273 reads (21%) | called by muse, mutect2, varscan2
- GMNC | c.393C>G p.L131= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs1232818024; called by muse, mutect2, varscan2
- GPR4 | c.681C>T p.L227= | Silent (SNP) | VAF 44/94 reads (47%) | catalogued as rs745816716, COSV100547211; called by muse, mutect2, varscan2
- HLA-DPB1 | c.138G>A p.A46= | Silent (SNP) | VAF 43/99 reads (43%) | catalogued as COSV101330983; called by muse, mutect2, varscan2
- HOXC10 | c.360G>A p.A120= | Silent (SNP) | VAF 41/97 reads (42%) | catalogued as rs755531147, COSV57725749; called by muse, mutect2, varscan2
- HSDL1 | c.144C>T p.I48= | Silent (SNP) | VAF 44/62 reads (71%) | catalogued as rs140132616; called by muse, mutect2, varscan2
- KALRN | c.2133G>A p.A711= | Silent (SNP) | VAF 37/68 reads (54%) | catalogued as rs771916960, COSV53760606; called by muse, mutect2, varscan2
- MAP1S | c.2397C>T p.P799= | Silent (SNP) | VAF 34/67 reads (51%) | catalogued as rs763819840; called by muse, mutect2, varscan2
- MECP2 | c.1032G>A p.R344= | Silent (SNP) | VAF 33/66 reads (50%) | called by muse, mutect2, varscan2
- OGDH | c.1278C>T p.L426= | Silent (SNP) | VAF 43/111 reads (39%) | catalogued as rs368814406; called by muse, mutect2, varscan2
- OR4K15 | c.270G>C p.L90= (on ENST00000305051; = p.L66= on NM_001005486.1) | Silent (SNP) | VAF 30/117 reads (26%) | catalogued as COSV59303651; called by muse, mutect2, varscan2
- PERP | c.156C>T p.S52= | Silent (SNP) | VAF 38/87 reads (44%) | called by muse, mutect2, varscan2
- PIK3R4 | c.1065C>T p.H355= | Silent (SNP) | VAF 76/277 reads (27%) | called by muse, mutect2, varscan2
- PLA2G4E | c.1887C>T p.T629= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs1380803750; called by muse, varscan2
- PLK2 | c.558C>T p.L186= | Silent (SNP) | VAF 16/54 reads (30%) | called by muse, mutect2, varscan2
- PPP2R2C | c.867C>T p.F289= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as rs757601971; called by muse, mutect2, varscan2
- PSME4 | c.154C>T p.L52= | Silent (SNP) | VAF 24/46 reads (52%) | called by muse, mutect2
- RNFT2 | c.912G>A p.L304= | Silent (SNP) | VAF 35/96 reads (36%) | catalogued as rs1018325903; called by muse, mutect2, varscan2
- SLC22A11 | c.1104G>A p.Q368= | Silent (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- SLC4A1 | c.1881C>G p.T627= | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as COSV52260694; called by muse, mutect2, varscan2
- SPRR1B | c.264G>A p.Q88= | Silent (SNP) | VAF 68/381 reads (18%) | catalogued as COSV61068108; called by muse, mutect2, varscan2
- TEP1 | c.5496C>G p.L1832= | Silent (SNP) | VAF 56/145 reads (39%) | called by muse, mutect2
- TRMT1 | c.1485C>G p.L495= | Silent (SNP) | VAF 46/84 reads (55%) | called by muse, mutect2, varscan2
- TTLL7 | c.2424G>A p.Q808= | Silent (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
- UGCG | c.177G>A p.L59= | Silent (SNP) | VAF 19/103 reads (18%) | catalogued as COSV65336408; called by muse, mutect2, varscan2
- ZDHHC2 | c.81C>T p.T27= | Silent (SNP) | VAF 21/21 reads (100%) | catalogued as rs1201069748; called by muse, mutect2, varscan2
- ZNF273 | c.195G>C p.V65= | Silent (SNP) | VAF 8/192 reads (4%) | called by muse, mutect2
- ZNF285 | c.1563C>T p.F521= | Silent (SNP) | VAF 70/154 reads (45%) | catalogued as COSV58411112; called by muse, mutect2, varscan2
- ZNF37A | c.930G>A p.K310= | Silent (SNP) | VAF 38/82 reads (46%) | catalogued as COSV61072606; called by muse, mutect2, varscan2
- ZNF438 | c.1125G>A p.L375= | Silent (SNP) | VAF 87/331 reads (26%) | called by muse, mutect2, varscan2
- ZNF799 | c.153C>T p.N51= | Silent (SNP) | VAF 48/89 reads (54%) | called by muse, mutect2, varscan2
- A2ML1 | c.1477-315G>C | Intron (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- AAGAB | c.535+4904G>A | Intron (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- ABCE1 | c.*1201G>A | 3'UTR (SNP) | VAF 26/47 reads (55%) | called by muse, mutect2, varscan2
- AC084082.1 | n.52C>A | RNA (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2
- ACTR10 | c.*220C>T | 3'UTR (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- ADAMTS18 | c.*1407C>T | 3'UTR (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- AHRR | c.709-138C>T | Intron (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- AHSA1 | c.792+61C>T | Intron (SNP) | VAF 59/153 reads (39%) | called by muse, mutect2, varscan2
- AK3 | c.*1850C>T | 3'UTR (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2
- ALB | c.482+104G>C | Intron (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
- ALDH1L1 | c.2182-78G>A | Intron (SNP) | VAF 16/84 reads (19%) | called by muse, mutect2
- ALDH7A1 | c.*1733C>T | 3'UTR (SNP) | VAF 47/104 reads (45%) | called by muse, mutect2, varscan2
- ANKRD17 | c.*2587G>T | 3'UTR (SNP) | VAF 10/39 reads (26%) | catalogued as rs1339337619; called by muse, mutect2, varscan2
- ANXA11 | c.*3984G>C | 3'UTR (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2, varscan2
- ANXA2 | c.-131C>G | 5'UTR (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2
- AP001830.2 | n.366C>T | RNA (SNP) | VAF 53/113 reads (47%) | called by muse, mutect2, varscan2
- API5 | c.1492+106G>A | Intron (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- B4GALNT1 | c.*2825C>G | 3'UTR (SNP) | VAF 18/85 reads (21%) | called by muse, mutect2, varscan2
- BCL10 | c.-231C>T | 5'UTR (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
- BEND4 | c.*5126C>A | 3'UTR (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- BMPR2 | c.*7268G>A | 3'UTR (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- BNC2 | c.*2315G>T | 3'UTR (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- BPTF | c.8918-47G>A | Intron (SNP) | VAF 28/53 reads (53%) | called by muse, mutect2, varscan2
- C12orf76 | n.1539C>T | RNA (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- C1orf21 | c.*6395T>C | 3'UTR (SNP) | VAF 4/65 reads (6%) | called by muse, mutect2
- C2CD6 | c.1581+3320G>A | Intron (SNP) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- CA14 | c.76+104C>T | Intron (SNP) | VAF 18/236 reads (8%) | called by muse, mutect2
- CACNG8 | c.*4811G>A | 3'UTR (SNP) | VAF 42/101 reads (42%) | catalogued as rs763038474; called by muse, mutect2, varscan2
- CAND1 | c.*738G>A | 3'UTR (SNP) | VAF 34/69 reads (49%) | catalogued as COSV101607288; called by muse, mutect2, varscan2
- CCDC162P | n.2748C>A | RNA (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
- CCDC8 | c.*65C>G | 3'UTR (SNP) | VAF 47/138 reads (34%) | called by muse, mutect2, varscan2
- CDHR1 | c.*1540C>G | 3'UTR (SNP) | VAF 35/71 reads (49%) | called by muse, mutect2, varscan2
- CDK19 | c.*1334C>G | 3'UTR (SNP) | VAF 19/38 reads (50%) | called by muse, mutect2, varscan2
- CDK9 | c.*569T>G | 3'UTR (SNP) | VAF 11/51 reads (22%) | catalogued as rs1313890301; called by muse, mutect2, varscan2
- CDON | c.*4566C>T | 3'UTR (SNP) | VAF 27/72 reads (38%) | called by muse, mutect2, varscan2
- CHN2 | c.-21C>T | 5'UTR (SNP) | VAF 38/38 reads (100%) | catalogued as rs1345360945; called by muse, mutect2, varscan2
- CLCN3 | c.*1519C>T | 3'UTR (SNP) | VAF 40/92 reads (43%) | called by muse, mutect2, varscan2
- CLK2P1 | n.947G>C | RNA (SNP) | VAF 46/105 reads (44%) | called by muse, mutect2, varscan2
- COL19A1 | c.*546G>T | 3'UTR (SNP) | VAF 26/66 reads (39%) | called by muse, mutect2, varscan2
- CREB3L2 | c.*4781C>T | 3'UTR (SNP) | VAF 15/67 reads (22%) | called by muse, mutect2, varscan2
- CROCCP2 | n.495+7012G>C | Intron (SNP) | VAF 9/90 reads (10%) | called by muse, varscan2
- CYP2E1 | c.*142A>G | 3'UTR (SNP) | VAF 16/16 reads (100%) | called by muse, mutect2, varscan2
- CYREN | c.138-26C>T | Intron (SNP) | VAF 28/137 reads (20%) | called by muse, mutect2, varscan2
- DBNL | c.*952G>A | 3'UTR (SNP) | VAF 29/69 reads (42%) | called by muse, mutect2, varscan2
- DCTPP1 | c.212+171C>G | Intron (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- DCTPP1 | c.102-43C>T | Intron (SNP) | VAF 20/43 reads (47%) | called by muse, varscan2
- DNAH10 | c.13307-266G>C | Intron (SNP) | VAF 28/71 reads (39%) | called by muse, mutect2, varscan2
- DNAJC11 | c.1323+99C>G | Intron (SNP) | VAF 17/71 reads (24%) | called by muse, mutect2, varscan2
- DOCK4 | c.*141C>T | 3'UTR (SNP) | VAF 22/84 reads (26%) | catalogued as rs539290512; called by muse, mutect2, varscan2
- DTX1 | c.-124A>C | 5'UTR (SNP) | VAF 34/56 reads (61%) | called by muse, mutect2, varscan2
- ECE1 | c.139-182G>C | Intron (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- EPOP | c.*566G>C | 3'UTR (SNP) | VAF 21/87 reads (24%) | catalogued as rs1333719110; called by muse, mutect2, varscan2
- ERMARD | c.990+351G>A | Intron (SNP) | VAF 26/27 reads (96%) | called by muse, mutect2, varscan2
- EXOC5 | c.856-25C>T | Intron (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- FAM149B1 | c.*3261G>A | 3'UTR (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- FBXO3 | c.1239+2215G>C | Intron (SNP) | VAF 23/57 reads (40%) | called by muse, mutect2, varscan2
- FGF17 | c.*115G>A | 3'UTR (SNP) | VAF 14/14 reads (100%) | called by muse, mutect2, varscan2
- FLOT2 | c.132-1620G>A | Intron (SNP) | VAF 28/51 reads (55%) | called by muse, mutect2, varscan2
- GABRB2 | c.*3948G>A | 3'UTR (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- GADL1 | c.*816_*821del | 3'UTR (DEL) | VAF 4/32 reads (13%) | catalogued as rs1482761681; called by pindel, varscan2*
- GART | chr21:33542596 G>A | 5'Flank (SNP) | VAF 24/60 reads (40%) | called by muse, mutect2
- GLB1L3 | chr11:134275966 G>A | 5'Flank (SNP) | VAF 93/194 reads (48%) | called by muse, mutect2, varscan2
- GRIN2A | c.*8297C>T | 3'UTR (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- GYPB | c.*2G>T | 3'UTR (SNP) | VAF 25/52 reads (48%) | called by muse, mutect2, varscan2
- HABP4 | c.-41C>T | 5'UTR (SNP) | VAF 12/51 reads (24%) | catalogued as rs1476502613; called by muse, mutect2, varscan2
- HAPLN1 | c.472+262G>A | Intron (SNP) | VAF 31/72 reads (43%) | called by muse, mutect2, varscan2
- HDAC3 | c.*154T>C | 3'UTR (SNP) | VAF 14/69 reads (20%) | called by muse, mutect2, varscan2
- HDHD2 | c.677-63G>A | Intron (SNP) | VAF 37/121 reads (31%) | called by muse, mutect2, varscan2
- HES1 | c.-45C>T | 5'UTR (SNP) | VAF 31/79 reads (39%) | called by muse, mutect2, varscan2
- HNRNPU | chr1:244853528 G>A | 3'Flank (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- IFNLR1 | c.*93C>A | 3'UTR (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- IFRD2 | chr3:50292691 C>A | 5'Flank (SNP) | VAF 48/106 reads (45%) | called by muse, mutect2, varscan2
- IL36RN | c.*165G>A | 3'UTR (SNP) | VAF 12/34 reads (35%) | catalogued as rs529172925; called by muse, varscan2
- IL6ST | c.*666C>G | 3'UTR (SNP) | VAF 16/28 reads (57%) | called by muse, mutect2, varscan2
- IQCD | c.-93-135C>T | Intron (SNP) | VAF 21/43 reads (49%) | called by muse, mutect2, varscan2
- KCNJ11 | c.*329C>G | 3'UTR (SNP) | VAF 49/96 reads (51%) | called by muse, mutect2, varscan2
- KCNT1 | c.3100-26G>A | Intron (SNP) | VAF 28/102 reads (27%) | catalogued as rs765986240; called by mutect2, varscan2
- KDELR2 | c.*399G>C | 3'UTR (SNP) | VAF 37/106 reads (35%) | called by muse, mutect2, varscan2
- KIAA1549L | c.*1662C>T | 3'UTR (SNP) | VAF 19/50 reads (38%) | called by muse, mutect2, varscan2
- KPNA6 | c.*983G>A | 3'UTR (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2
- KRR1 | c.*1557C>T | 3'UTR (SNP) | VAF 29/60 reads (48%) | called by muse, mutect2, varscan2
- KRT6B | c.*217G>T | 3'UTR (SNP) | VAF 18/32 reads (56%) | called by muse, mutect2, varscan2
- LANCL1 | chr2:210431471 G>C | 3'Flank (SNP) | VAF 28/72 reads (39%) | called by muse, mutect2, varscan2
- LCLAT1 | c.*974G>C | 3'UTR (SNP) | VAF 24/53 reads (45%) | called by muse, mutect2, varscan2
- LEMD2 | c.931-95G>T | Intron (SNP) | VAF 36/74 reads (49%) | called by muse, mutect2, varscan2
- LGR4 | c.*1100C>T | 3'UTR (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- LIF | c.*1879G>A | 3'UTR (SNP) | VAF 38/99 reads (38%) | catalogued as rs962151603; called by muse, mutect2, varscan2
- LIMK1 | c.*926G>C | 3'UTR (SNP) | VAF 26/78 reads (33%) | called by muse, mutect2, varscan2
- LINC01511 | n.437-8107G>A | Intron (SNP) | VAF 41/83 reads (49%) | called by muse, mutect2, varscan2
- LMNA | c.*422G>A | 3'UTR (SNP) | VAF 28/35 reads (80%) | called by muse, mutect2, varscan2
- LRP1 | c.-110G>C | 5'UTR (SNP) | VAF 8/24 reads (33%) | called by muse, varscan2
- MED13L | c.4114+38C>A | Intron (SNP) | VAF 10/18 reads (56%) | called by muse, varscan2
- MED28 | c.*6297C>A | 3'UTR (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- MFN2 | c.*737C>A | 3'UTR (SNP) | VAF 46/85 reads (54%) | called by muse, mutect2, varscan2
- MFN2 | c.*1134C>G | 3'UTR (SNP) | VAF 44/99 reads (44%) | called by muse, mutect2, varscan2
- MLLT3 | c.*1977C>T | 3'UTR (SNP) | VAF 34/105 reads (32%) | called by muse, mutect2, varscan2
- MPHOSPH6 | c.*528G>C | 3'UTR (SNP) | VAF 38/72 reads (53%) | called by muse, mutect2, varscan2
- MRNIP | c.126+95C>T | Intron (SNP) | VAF 26/65 reads (40%) | catalogued as rs1280997040, COSV52974126; called by muse, mutect2, varscan2
- MTERF1 | c.*1956C>G | 3'UTR (SNP) | VAF 20/51 reads (39%) | called by muse, mutect2, varscan2
- MTX2 | c.*231G>A | 3'UTR (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- MYC | c.*88C>G | 3'UTR (SNP) | VAF 16/54 reads (30%) | called by muse, mutect2, varscan2
- MYC | c.*419C>G | 3'UTR (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- MYO1E | c.*902G>C | 3'UTR (SNP) | VAF 21/43 reads (49%) | called by muse, mutect2, varscan2
- MYOF | c.4327-33G>A | Intron (SNP) | VAF 38/105 reads (36%) | catalogued as COSV63712567; called by muse, mutect2, varscan2
- MYRFL | c.-172C>G | 5'UTR (SNP) | VAF 13/44 reads (30%) | catalogued as rs977408155; called by muse, mutect2, varscan2
- NAGK | chr2:71068394 C>G | 5'Flank (SNP) | VAF 33/82 reads (40%) | called by muse, mutect2, varscan2
- NCAM2 | c.*368delinsTC | 3'UTR (INS) | VAF 19/89 reads (21%) | called by mutect2*, pindel, varscan2*
- NFYB | c.*176C>G | 3'UTR (SNP) | VAF 43/86 reads (50%) | called by muse, mutect2, varscan2
- NLN | c.*6027G>C | 3'UTR (SNP) | VAF 42/82 reads (51%) | called by muse, mutect2, varscan2
- NPTXR | c.*110C>G | 3'UTR (SNP) | VAF 29/45 reads (64%) | called by muse, mutect2, varscan2
- NUDT5 | c.550+177G>C | Intron (SNP) | VAF 13/61 reads (21%) | called by muse, mutect2, varscan2
- NUF2 | c.510-93C>G | Intron (SNP) | VAF 10/16 reads (63%) | called by muse, mutect2, varscan2
- NXPH3 | c.-39G>C | 5'UTR (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- OPRL1 | c.*363C>G | 3'UTR (SNP) | VAF 24/109 reads (22%) | called by muse, mutect2, varscan2
- OR4D9 | c.*50C>G | 3'UTR (SNP) | VAF 57/127 reads (45%) | called by muse, mutect2, varscan2
- ORAI2 | c.*9280G>C | 3'UTR (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- PARD3B | c.*3931C>G | 3'UTR (SNP) | VAF 20/72 reads (28%) | called by muse, mutect2, varscan2
- PDE4D | c.809-130G>A | Intron (SNP) | VAF 17/33 reads (52%) | called by muse, mutect2, varscan2
- PGR | c.*8971G>A | 3'UTR (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- PHC1P1 | n.2359C>G | RNA (SNP) | VAF 59/128 reads (46%) | called by muse, mutect2, varscan2
- PHLDB2 | c.1720-1681G>A | Intron (SNP) | VAF 33/64 reads (52%) | called by muse, mutect2, varscan2
- PIP4K2C | c.*15C>G | 3'UTR (SNP) | VAF 41/135 reads (30%) | called by muse, mutect2, varscan2
- PKD1L2 | n.367G>T | RNA (SNP) | VAF 37/38 reads (97%) | called by muse, mutect2, varscan2
- POU2F2 | c.*636C>T | 3'UTR (SNP) | VAF 37/86 reads (43%) | called by muse, mutect2, varscan2
- PPIP5K1 | c.*496G>C | 3'UTR (SNP) | VAF 34/81 reads (42%) | called by muse, mutect2, varscan2
- PPP1R8 | c.56+42G>A | Intron (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- PPP2R5A | c.-122G>C | 5'UTR (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- PPP3R1 | c.*222G>C | 3'UTR (SNP) | VAF 40/81 reads (49%) | called by muse, mutect2, varscan2
- PPP3R1 | c.*37C>G | 3'UTR (SNP) | VAF 4/86 reads (5%) | catalogued as rs935085030; called by muse, mutect2
- PRR14L | c.*1393G>A | 3'UTR (SNP) | VAF 33/56 reads (59%) | called by muse, mutect2, varscan2
- PRSS16 | c.*292G>A | 3'UTR (SNP) | VAF 50/89 reads (56%) | called by muse, mutect2, varscan2
- PSMD6 | c.996-30T>C | Intron (SNP) | VAF 41/64 reads (64%) | called by muse, mutect2, varscan2
- PTMA | c.46-765C>T | Intron (SNP) | VAF 33/64 reads (52%) | called by muse, mutect2, varscan2
- PXN | c.934-107C>G | Intron (SNP) | VAF 32/66 reads (48%) | called by muse, mutect2, varscan2
- PYCR2 | c.-46C>A | 5'UTR (SNP) | VAF 8/26 reads (31%) | catalogued as rs774149360; called by muse, mutect2, varscan2
- RAB27B | c.*3395G>A | 3'UTR (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- RBPJ | c.535+58C>G | Intron (SNP) | VAF 47/80 reads (59%) | called by muse, mutect2, varscan2
- RGS3 | c.1915-95C>A | Intron (SNP) | VAF 24/58 reads (41%) | catalogued as rs1308183899; called by muse, varscan2
- RGS3 | c.1915-21C>G | Intron (SNP) | VAF 38/112 reads (34%) | called by muse, varscan2
- RHOT1 | chr17:32141469 C>T | 5'Flank (SNP) | VAF 31/57 reads (54%) | called by muse, mutect2, varscan2
- RNF38 | c.*2251C>G | 3'UTR (SNP) | VAF 17/83 reads (20%) | called by muse, mutect2, varscan2
- RPA2 | chr1:27914588 C>T | 5'Flank (SNP) | VAF 37/158 reads (23%) | called by muse, mutect2, varscan2
- RPUSD4 | c.557+15G>A | Intron (SNP) | VAF 44/95 reads (46%) | catalogued as rs376181613; called by muse, mutect2, varscan2
- RTKN2 | c.*1805G>A | 3'UTR (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- RTKN2 | c.*1528G>A | 3'UTR (SNP) | VAF 28/64 reads (44%) | called by muse, mutect2, varscan2
- RUNX1 | c.*773C>T | 3'UTR (SNP) | VAF 56/92 reads (61%) | called by muse, mutect2, varscan2
- SEC14L1 | c.-240+376del | Intron (DEL) | VAF 7/20 reads (35%) | called by mutect2, pindel, varscan2
- SEC22C | c.*5070C>T | 3'UTR (SNP) | VAF 31/74 reads (42%) | called by muse, mutect2, varscan2
- SELENBP1 | c.1044+94G>C | Intron (SNP) | VAF 52/68 reads (76%) | called by muse, mutect2, varscan2
- SERP1 | c.-294C>G | 5'UTR (SNP) | VAF 51/120 reads (43%) | called by muse, mutect2, varscan2
- SGMS1 | c.*607G>A | 3'UTR (SNP) | VAF 48/98 reads (49%) | called by muse, mutect2, varscan2
- SLC15A4 | c.843-112G>A | Intron (SNP) | VAF 26/74 reads (35%) | called by muse, mutect2, varscan2
- SLC37A4 | c.*100C>G | 3'UTR (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- SLC9A8 | c.*3914C>A | 3'UTR (SNP) | VAF 36/68 reads (53%) | called by muse, mutect2, varscan2
- SLC9A9 | c.*397G>C | 3'UTR (SNP) | VAF 42/76 reads (55%) | called by muse, mutect2
- ST3GAL1 | c.*4684G>C | 3'UTR (SNP) | VAF 30/78 reads (38%) | called by muse, mutect2, varscan2
- STAG2 | chrX:124101678 C>G | 3'Flank (SNP) | VAF 8/10 reads (80%) | called by muse, mutect2, varscan2
- SURF6 | c.*1171G>C | 3'UTR (SNP) | VAF 20/35 reads (57%) | called by muse, mutect2, varscan2
- TAB1 | chr22:39436820 C>G | 3'Flank (SNP) | VAF 37/87 reads (43%) | called by muse, mutect2, varscan2
- TAF4 | c.*1056G>C | 3'UTR (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- TEKT4P2 | n.1417C>G | RNA (SNP) | VAF 21/172 reads (12%) | called by muse, mutect2, varscan2
- TMEM132D | c.1444-13C>T | Intron (SNP) | VAF 12/45 reads (27%) | catalogued as rs1373998093, COSV101242525; called by muse, mutect2, varscan2
- TMEM199 | c.211+15C>G | Intron (SNP) | VAF 30/107 reads (28%) | called by muse, mutect2, varscan2
- TOR1B | c.*1021G>A | 3'UTR (SNP) | VAF 29/78 reads (37%) | called by muse, mutect2, varscan2
- TPD52L1 | c.*731_*732insC | 3'UTR (INS) | VAF 8/34 reads (24%) | called by mutect2, varscan2
- TRIM11 | c.*643C>T | 3'UTR (SNP) | VAF 56/120 reads (47%) | called by muse, mutect2, varscan2
- TRIM14 | c.*2243G>A | 3'UTR (SNP) | VAF 29/193 reads (15%) | called by muse, mutect2, varscan2
- TRIM16 | chr17:15684272 C>T | 5'Flank (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- TRIM23 | chr5:65624484 C>T | 5'Flank (SNP) | VAF 28/57 reads (49%) | called by muse, mutect2, varscan2
- TRIM46 | c.1285+207C>T | Intron (SNP) | VAF 58/179 reads (32%) | catalogued as rs1407177700; called by muse, mutect2, varscan2
- TSLP | chr5:111070809 G>T | 5'Flank (SNP) | VAF 19/41 reads (46%) | called by muse, mutect2, varscan2
- TTN | c.10361-4431C>A | Intron (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
- TXNL1 | c.*5390G>A | 3'UTR (SNP) | VAF 28/157 reads (18%) | called by muse, mutect2, varscan2
- UBQLN1 | c.-25C>G | 5'UTR (SNP) | VAF 6/32 reads (19%) | catalogued as rs1025088538; called by muse, mutect2
- UBXN1 | c.651+45C>T | Intron (SNP) | VAF 15/34 reads (44%) | catalogued as rs980365691; called by muse, mutect2, varscan2
- USP37 | c.*3557A>G | 3'UTR (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- WASL | c.-6G>A | 5'UTR (SNP) | VAF 26/56 reads (46%) | catalogued as rs773018491; called by muse, mutect2, varscan2
- ZNF564 | c.*493G>T | 3'UTR (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2, varscan2
- ZNF688 | c.-116C>T | 5'UTR (SNP) | VAF 26/41 reads (63%) | called by muse, mutect2, varscan2
- ZNF705G | c.*1564A>G | 3'UTR (SNP) | VAF 31/102 reads (30%) | called by muse, mutect2
- ZNF823 | c.-97G>C | 5'UTR (SNP) | VAF 21/76 reads (28%) | called by muse, mutect2, varscan2
- ZYG11B | c.*3278C>G | 3'UTR (SNP) | VAF 20/43 reads (47%) | catalogued as rs375773990; called by muse, mutect2, varscan2
